TCGA case TCGA-RA-A741 — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Candler. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bdad2f13-ede2-4aad-91a4-bf60f8888bf2

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 34 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 34.5 years (12,607 days); Year of diagnosis: 2013; Method of diagnosis: Biopsy; FIGO stage: Stage IIB; FIGO staging edition year: 2009; Tumor grade: GX; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 4.
   Pathology details: Lymph node involved site: Pelvis, NOS.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 9 days; Days to treatment end: 76 days.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 9 days; Days to treatment end: 76 days; Treatment dose: 45 Gy; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, Internal; Days to treatment start: 37 days; Days to treatment end: 57 days; Treatment dose: 55 Gy; Number of fractions: 5; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 118 days; Days to treatment end: 254 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Days to treatment start: 233 days; Days to treatment end: 254 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Brachytherapy, High Dose; Treatment intent type: Adjuvant; Treatment dose: 5,500 cGy; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Number of cycles: 6; Chemo concurrent to radiation: Yes; Prescribed dose: 40; Prescribed dose units: mg/m2; Timepoint category: Postoperative; Treatment frequency: Once Weekly.
   Treatment given: Treatment type: Radiation, Intensity-Modulated Radiotherapy; Treatment intent type: Adjuvant; Treatment dose: 4,500 cGy; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative; Treatment anatomic sites: Pelvis.

Follow-up (8 entries)
- Day -15 (preoperative): Days to imaging: -15 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Pelvic Lymph Node Involvement.
- Day 0 (preoperative): ECOG performance status: 0.
- Day 14 (preoperative): Days to imaging: 14 days; Imaging type: MRI; Imaging result: Negative; Imaging findings: Parametrium Involvement.
- Day 14 (preoperative): Days to imaging: 14 days; Imaging type: MRI; Imaging result: Negative; Imaging findings: Pelvic Lymph Node Involvement.
- Day 14 (preoperative): Days to imaging: 14 days; Imaging type: MRI; Imaging result: Negative; Imaging findings: Paraaortic Lymph Node Involvement.
- Day 14 (preoperative): Days to imaging: 14 days; Imaging type: MRI; Imaging result: Negative; Imaging findings: Bladder Involvement.
- Day 444 (post adjuvant therapy): Disease response: Tumor Free; ECOG performance status: 0.
- Follow-up contact recording only the day: day 118.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 86 kg; Height: 165 cm; BMI: 31.6.
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal; Pregnant at diagnosis: No.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Ectopic Pregnancy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Stillbirth.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Induced Abortion.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Live Birth.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Miscarriage.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 10; Tobacco smoking quit year: 2013; Age at onset: 21.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-RA-A741-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 180 mg.
  Slide TCGA-RA-A741-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 5; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-RA-A741-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-RA-A741-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Live birth pregnancy count: 0; Pregnancies count miscarriage: 0; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Total pregnancy count: 0; Tobacco smoking history indicator: 4; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Lymph nodes examined: Yes; New tumor event diagnosis indicator: No.
- Lymph node location positive pathology names: Pos lymph node location: Pelvic (external iliac, internal iliac, obturator).
- Diagnostic mri result outcomes: Lymph nodes supraclavicular: Bladder Absent; Lymph nodes supraclavicular: Parametrium Absent; Lymph nodes supraclavicular: Paraaortic Nodes Absent; Lymph nodes supraclavicular: Pelvic Nodes Absent.
- Diagnostic ct result outcomes: Ct scan preop results: Pelvic Nodes Absent.
- Treatment, Radiation therapy info: Brachytherapy type: HDR; Radiation therapy xrt type: Imrt.
- Treatment, Concurrent prescription treatment info, Concurrent prescription treatment: Chemo concurrent dose: 40 MG/M2; Chemo concurrent fractions total: 6.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Performance status timing: Post-Adjuvant Therapy; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form, Treatment, Concurrent prescription treatment info, Concurrent prescription treatment: Chemo concurrent dose: 75; Chemo concurrent fractions total: 5.
- Drug treatment 4: Pharmaceutical therapy drug name: avastin.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 444 days; disease-specific survival: no event (censored), 444 days; disease-free interval: no event (censored), 444 days; progression-free interval: no event (censored), 444 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-RA-A741-01A-11D-A33N-01): tumor purity 0.86, ploidy 1.98, whole-genome doublings 0.
